Somatic mutation profile of tumor specimen TCGA-P5-A72Z-01A (aliquot TCGA-P5-A72Z-01A-11D-A32B-08) from TCGA case TCGA-P5-A72Z, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 64.3 years (23,482 days).
Specimen TCGA-P5-A72Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3488c0c-bf50-4061-8211-3e90586531e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A72Z-10A (Blood Derived Normal), aliquot TCGA-P5-A72Z-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6faea6e7-4daf-44b8-93ef-a4992653cdeb

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Del 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.691A>G p.S231G | Missense Mutation (SNP) | VAF 34/36 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99359121; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/42 reads (60%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD8 | c.980A>G p.E327G | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV99917146; called by muse, mutect2, varscan2
- CHAT | c.818A>C p.Y273S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100339859; called by muse, varscan2
- DIP2C | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 6/146 reads (4%) | catalogued as COSV99790420; called by muse, mutect2
- GLB1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs375582374, CM042715; called by muse, mutect2, varscan2
- HMGCLL1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.072); catalogued as rs201456410, COSV51449306; called by muse, mutect2, varscan2
- JPH1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60613963; called by muse, mutect2
- KCNJ12 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.527); catalogued as rs782149484, COSV59175677; called by muse, mutect2
- KDM5B | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV99350191; called by muse, mutect2, varscan2
- KDM5C | c.2786G>A p.R929Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs782148639, COSV100948852; called by muse, mutect2, varscan2
- LCE3E | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.922); catalogued as rs530968216, COSV64232346; called by muse, mutect2
- LCT | c.3665A>G p.N1222S | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.1); catalogued as rs1192088205, COSV99928785; called by muse, mutect2, varscan2
- NLRP2 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs200623569; called by muse, mutect2, varscan2
- OR51I2 | c.334T>C p.S112P | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100413320; called by muse, mutect2, varscan2
- PIKFYVE | c.2515A>G p.I839V | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1381694770, COSV100010029; called by muse, mutect2, varscan2
- PPM1B | c.287A>T p.E96V | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99175700; called by muse, mutect2, varscan2
- PTPRD | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.758); catalogued as rs758577045, COSV100642816, COSV61995148; called by muse, mutect2, varscan2
- SCP2D1 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99601915; called by muse, mutect2, varscan2
- WSB1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99285923; called by muse, mutect2, varscan2
- HELZ2 | c.225del p.W76Gfs*95 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- NIPBL | c.3621_3622del p.N1208Yfs*4 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by pindel, varscan2
- ACOT9 | c.1065C>T p.L355= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100321213; called by muse, mutect2, varscan2
- ARFIP1 | c.261A>G p.R87= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100617046; called by muse, mutect2, varscan2
- C11orf16 | c.1251G>A p.Q417= | Silent (SNP) | VAF 7/124 reads (6%) | catalogued as COSV100214874; called by muse, mutect2
- DST | c.17844C>T p.I5948= (on ENST00000361203 / NM_001374722.1; = p.I3645= on NM_015548.5) | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV99752215; called by muse, mutect2, varscan2
- OR2A14 | c.504C>T p.C168= | Silent (SNP) | VAF 172/416 reads (41%) | catalogued as rs759968987, COSV101376444; called by muse, mutect2
- PDZD4 | c.2136C>T p.G712= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV51245204; called by muse, mutect2, varscan2
- RIPOR1 | c.999T>G p.S333= (on ENST00000379312 / NM_001193522.2; = p.S329= on NM_024519.4) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs377549645; called by muse, mutect2, varscan2
- SYNE1 | c.15198C>T p.T5066= (on ENST00000367255 / NM_182961.4; = p.T4995= on NM_033071.3) | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs370314344, COSV55037671; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700697 C>T | 3'Flank (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
